CCDI case PBCRIF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and ill-defined sites within respiratory system and intrathoracic organs.
https://portal.gdc.cancer.gov/cases/e69629de-cfb2-4fb6-a8f8-975691fb520f

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Clear cell adenocarcinoma, NOS: ICD-O-3 morphology code: 8310/3; Tissue or organ of origin: Lower lobe, lung; Age at diagnosis: 20.1 years (7,333 days).

Biospecimens (3 samples)
- Sample 0DXJEI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DXJGO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DXJH6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
